Gene-level copy-number profile of tumor specimen C3L-03985-03 (profiled together with C3L-03985-04) from CPTAC case C3L-03985, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 67.7 years (24,731 days).
Specimen C3L-03985-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7509f095-92c5-49da-8f7b-30876ebecc3b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03985-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,752 have no estimate.
https://portal.gdc.cancer.gov/files/c12e1192-8e5f-44ae-a93d-11060caf469f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 4,019; copy number 2: 24,888; copy number 3: 17,651; copy number 4: 7,203; copy number 5: 4,249; copy number 6: 605; copy number 7: 139; copy number 8: 4; copy number 9: 35; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,589,323–28,648,733, 5 genes (within-gene range 0–1): TAF12, RAB42, LINC01715, AL360012.1, RNU11.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr9:41,131,306–41,237,557, 3 genes (within-gene range 0–2): CBWD6, MIR4477A, RNA5SP530.
- chr9:41,292,887–41,355,538, 3 genes: MYO5BP1, AL354718.2, CDRT15P6.
- chr9:42,566,679–42,569,353, 2 genes: BX088651.4, BX088651.1.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,894 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–159,925,507, 728 genes, copy number 5–6 (broad region; genes not listed).
- chr1:161,983,192–168,729,206, 137 genes, copy number 5 (broad region; genes not listed).
- chr1:168,763,365–168,792,886, 2 genes, copy number 5: AL031275.1, LINC00626.
- chr3:84,638,405–86,074,429, 5 genes, copy number 6 (within-gene range 4–6): LINC00971, AC117482.1, LINC02025, CADM2, MIR5688.
- chr3:98,706,236–99,529,985, 13 genes, copy number 5: ST3GAL6-AS1, ST3GAL6, PDLIM1P4, DCBLD2, RNU6-26P, AC091212.1, RNU6-1263P, LINC00973, U7, ACTG1P13, AC107297.1, AC078828.1, AC107029.1.
- chr3:176,415,439–177,323,418, 10 genes, copy number 6: LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7.
- chr4:68,537,184–68,616,137, 3 genes, copy number 5: UGT2B17, AC147055.2, AC147055.4.
- chr4:68,646,597–68,670,652, 1 gene, copy number 5: UGT2B15.
- chr4:69,280,475–69,358,177, 3 genes, copy number 5: UGT2B28, AC114786.3, AC114786.2.
- chr4:69,408,828–69,423,164, 1 gene, copy number 5 (within-gene range 2–5): UGT2B24P.
- chr5:19,471,296–43,603,230, 318 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:51,716,657–67,362,950, 353 genes, copy number 5 (broad region; genes not listed).
- chr7:84,528,122–84,584,322, 2 genes, copy number 5: RPL7P30, AC003984.1.
- chr7:108,720,608–111,562,517, 16 genes, copy number 5 (within-gene range 4–5): AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, IMMP2L, AC073326.1, LRRN3.
- chr8:59,119,040–141,060,596, 1,114 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:41,644,438–41,648,035, 3 genes, copy number 9: AL591926.7, AL591926.6, AL591926.5.
- chr11:49,871,826–50,422,316, 23 genes, copy number 5: AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr12:12,310–1,922,867, 44 genes, copy number 6–9: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2.
- chr12:3,381,349–3,593,973, 4 genes, copy number 5: PRMT8, AC005908.2, AC005908.1, THCAT155.
- chr12:22,573,425–22,690,665, 4 genes, copy number 5: LRRC34P1, AC087241.1, AC087241.2, ETNK1.
- chr12:23,529,504–24,562,544, 1 gene, copy number 10 (within-gene range 2–10): SOX5.
- chr12:24,212,421–25,409,445, 25 genes, copy number 6 (within-gene range 2–6): MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:27,696,388–28,978,685, 26 genes, copy number 5 (within-gene range 2–5): AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1.
- chr12:30,169,881–30,217,916, 2 genes, copy number 6: AC023511.2, AC023511.1.
- chr12:33,374,238–42,070,625, 67 genes, copy number 5–6 (broad region; genes not listed).
- chr12:42,157,104–92,952,745, 1,138 genes, copy number 5–6 (broad region; genes not listed).
- chr15:19,955,300–19,968,352, 3 genes, copy number 5: AC127381.2, IGHV1OR15-9, SLC20A1P3.
- chr17:40,748,021–40,755,331, 1 gene, copy number 5: KRT25.
- chr17:43,444,707–43,706,709, 10 genes, copy number 5: MIR2117HG, MIR2117, RNU6-406P, RNU6-971P, AC087650.1, DHX8, ETV4, Metazoa_SRP, MEOX1, LINC02594.
- chr18:10,124,588–14,252,140, 127 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:9,068,763–13,169,103, 51 genes, copy number 5: PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1.
- chr20:47,950,797–64,327,972, 378 genes, copy number 6–8 (broad region; genes not listed).
- chr22:21,885,282–25,231,870, 243 genes, copy number 5 (broad region; genes not listed).
- chr22:30,554,635–31,338,021, 38 genes, copy number 5 (within-gene range 2–5): GAL3ST1, PES1, AC005006.1, TCN2, SLC35E4, DUSP18, AC003072.1, AC003072.2, OSBP2, MIR3200, EIF4HP2, MORC2-AS1, MORC2, TUG1, AC004542.5, AC004542.4, AC004542.6, AC004542.3, AC004542.2, AC004542.1, AC005005.4, RN7SL633P, SMTN, AC005005.3, SELENOM, AC005005.2, INPP5J, PLA2G3, AC005005.1, MIR3928, RNF185, RNF185-AS1, LIMK2, RNU6-1128P, Y_RNA, PIK3IP1, PIK3IP1-DT, RNA5SP496.

Autosomal genes at a single copy (total copy number 1): 2,275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
